Somatic mutation profile of tumor specimen TCGA-CH-5754-01A (aliquot TCGA-CH-5754-01A-11D-1576-08) from TCGA case TCGA-CH-5754, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.2 years (23,803 days).
Specimen TCGA-CH-5754-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4caea0d-a964-4db8-853e-2c4d57313c52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5754-10A (Blood Derived Normal), aliquot TCGA-CH-5754-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbbb2026-7365-4633-8e2e-869d3b7774e4

The open-access MAF lists 104 somatic variants for this specimen: 74 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 29, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 2, Frame Shift Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59510705; called by muse, mutect2, varscan2
- ADAD2 | c.1387G>A p.A463T (on ENST00000315906 / NM_001145400.2; = p.A545T on NM_139174.4) | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs951758185, COSV51892554; called by muse, mutect2, varscan2
- ANO4 | c.1383G>C p.W461C (on ENST00000392977 / NM_001286615.2; = p.W426C on NM_178826.4) | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54597709; called by muse, mutect2, varscan2
- BANF2 | c.239A>C p.H80P | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV55724936; called by muse, mutect2, varscan2
- BMT2 | c.260C>G p.A87G | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs770968075, COSV51777141; called by muse, mutect2, varscan2
- BSCL2 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV54015905; called by muse, mutect2, varscan2
- CACYBP | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV62880353; called by muse, mutect2, varscan2
- CEP126 | c.823T>C p.S275P | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as rs776456092, COSV54825829; called by muse, mutect2, varscan2
- CEP63 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59676790; called by muse, mutect2, varscan2
- CRTAC1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 47/158 reads (30%) | catalogued as rs776273208, COSV54002538; called by muse, mutect2, varscan2
- CSPG4 | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV100413756, COSV57896074; called by muse, mutect2, varscan2
- CUX2 | c.4279G>A p.A1427T | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs746118929, COSV55634469; called by muse, mutect2
- DNAJC13 | c.2750T>C p.L917P | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV53451609; called by muse, mutect2
- EDN2 | c.242T>A p.L81Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65423474; called by muse, mutect2
- EPHB2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs139122679; called by muse, mutect2, varscan2
- ERCC2 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67263743; called by muse, mutect2, varscan2
- ESYT2 | c.1237G>C p.D413H (on ENST00000613624; = p.D337H on NM_020728.3) | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51751623; called by muse, mutect2, varscan2
- F13B | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV66374125; called by muse, mutect2, varscan2
- FAM83A | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs745825407, COSV52685669; called by muse, varscan2
- FOXN1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs769969790, COSV56880586, COSV56882002; called by muse, mutect2, varscan2
- FSCB | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 114/423 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61218289; called by muse, mutect2, varscan2
- GBE1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70099764; called by muse, mutect2, varscan2
- GFUS | c.449T>G p.I150S | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV71254298; called by muse, mutect2, varscan2
- GPR37L1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs1230960248, COSV66162367; called by muse, mutect2, varscan2
- GRHL2 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as COSV52549157; called by muse, mutect2, varscan2
- HYDIN | c.13487G>C p.R4496P | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200741838, COSV66639358; called by muse, mutect2, varscan2
- IGDCC3 | c.1614G>C p.Q538H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60077937; called by muse, varscan2
- IGSF10 | c.5068G>C p.D1690H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV56786148, COSV99180024; called by muse, mutect2, varscan2
- INTS14 | c.697C>G p.P233A (on ENST00000313182 / NM_001366360.2; = p.P154A on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs752461680, COSV57527281; called by muse, mutect2, varscan2
- INTS4 | c.92C>G p.T31R | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV71088680; called by muse, mutect2, varscan2
- IQGAP1 | c.2255T>A p.L752Q | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51586327; called by muse, mutect2, varscan2
- KANK1 | c.1165T>C p.S389P | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs776386850, COSV63212610; called by muse, mutect2, varscan2
- KIF24 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 146/499 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs374423056; called by muse, mutect2, varscan2
- LRRC36 | c.1430G>C p.W477S | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV52080082; called by muse, mutect2
- LRRC74A | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53610065; called by muse, mutect2, varscan2
- MASP1 | c.762A>C p.K254N | Missense Mutation (SNP) | VAF 176/650 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV51459719, COSV51460052, COSV99396788; called by muse, mutect2, varscan2
- MUC16 | c.15854C>A p.P5285H | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.253); catalogued as COSV67470399, COSV67500869; called by muse, mutect2, varscan2
- NLRP3 | c.1105C>A p.L369M | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as CM1310740, COSV60225300; called by muse, mutect2, varscan2
- NTN5 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as rs1025676409, COSV54307461; called by muse, varscan2
- NUP54 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53575874; called by muse, mutect2, varscan2
- NYNRIN | c.4364G>C p.W1455S | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV66842904; called by muse, mutect2, varscan2
- OR2AE1 | c.443C>A p.S148* | Nonsense Mutation (SNP) | VAF 59/193 reads (31%) | catalogued as COSV60390376; called by muse, mutect2, varscan2
- OR5P2 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV61490690; called by muse, mutect2, varscan2
- PCDHA1 | c.603T>A p.D201E | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65374714; called by muse, mutect2
- PGBD1 | c.2107G>C p.G703R | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52553734; called by muse, mutect2
- PREX2 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55774188; called by muse, mutect2, varscan2
- PRKN | c.978G>T p.Q326H | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV58230516; called by muse, mutect2, varscan2
- PSMD2 | c.2574G>C p.K858N | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV59530067; called by muse, mutect2, varscan2
- PTCHD4 | c.768C>G p.D256E | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV59786047; called by muse, mutect2
- RIMBP3 | c.2827G>A p.G943R | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.503); catalogued as rs777188969; called by muse, mutect2, varscan2
- SCN11A | c.1519C>A p.L507M | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV56571381; called by muse, mutect2, varscan2
- SLC35C2 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV54757216; called by muse, mutect2, varscan2
- SLC5A2 | c.789C>G p.Y263* | Nonsense Mutation (SNP) | VAF 11/117 reads (9%) | catalogued as COSV57892053; called by muse, mutect2
- SLC5A7 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 192/607 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV50888911, COSV50892599; called by muse, mutect2, varscan2
- SMARCAL1 | c.249C>G p.D83E | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.026); catalogued as COSV61921431; called by muse, mutect2, varscan2
- SNRNP200 | c.197A>C p.E66A | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60490357; called by muse, mutect2, varscan2
- SPAG6 | c.1226A>G p.Q409R | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV57620940; called by muse, mutect2
- TAF1L | c.3029C>T p.T1010I | Missense Mutation (SNP) | VAF 178/568 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54262838; called by muse, mutect2, varscan2
- TTBK2 | c.3007C>G p.L1003V | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV51162647; called by muse, mutect2
- UNC13C | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV52879379; called by muse, mutect2, varscan2
- VAV3 | c.224T>G p.I75R | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64068600; called by muse, mutect2, varscan2
- VIL1 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV50288920; called by muse, mutect2, varscan2
- VPS13D | c.4305T>G p.N1435K | Missense Mutation (SNP) | VAF 96/293 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as rs1462093072, COSV50643575, COSV99166092; called by muse, mutect2, varscan2
- ZNF410 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV57910975; called by muse, mutect2, varscan2
- ZNF432 | c.861A>T p.K287N | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55416944; called by muse, mutect2, varscan2
- ZNF518A | c.2880G>C p.L960F | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV60151613; called by muse, mutect2, varscan2
- ATAD2 | c.2855-4_2855del p.X952_splice | Splice Site (DEL) | VAF 22/140 reads (16%) | called by mutect2, pindel, varscan2
- BRCA2 | c.1298del p.N433Tfs*27 | Frame Shift Del (DEL) | VAF 72/234 reads (31%) | called by mutect2, pindel, varscan2
- BZW2 | c.1030_1035delinsACAGTAAA p.Q344Tfs*15 | Frame Shift Ins (INS) | VAF 65/247 reads (26%) | called by pindel, varscan2*
- EFNB2 | c.167_183del p.D56Vfs*7 | Frame Shift Del (DEL) | VAF 65/305 reads (21%) | called by mutect2, pindel*, varscan2*
- KLK1 | c.712_722del p.P238Ffs*? | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | called by mutect2, pindel
- RNASEH2C | c.476_487del p.A159_P162del | In Frame Del (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- SGSM1 | c.420_440del p.D141_L147del | In Frame Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel
- TPTE | c.1067C>G p.S356C (on ENST00000618007 / NM_199261.4; = p.S338C on NM_199259.4) | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CHRDL2 | c.369C>A p.I123= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV55223158; called by muse, mutect2
- CNOT4 | c.339T>G p.V113= | Silent (SNP) | VAF 58/207 reads (28%) | catalogued as COSV59653081; called by muse, mutect2, varscan2
- CSF3 | c.177A>G p.A59= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV56641020; called by muse, mutect2, varscan2
- DST | c.20850A>G p.K6950= (on ENST00000361203 / NM_001374722.1; = p.K4647= on NM_015548.5) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV55018275; called by muse, mutect2, varscan2
- FAM71E1 | c.318C>T p.D106= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV58542403; called by muse, mutect2, varscan2
- FANCM | c.2136T>G p.S712= | Silent (SNP) | VAF 70/205 reads (34%) | catalogued as COSV57501929; called by muse, mutect2, varscan2
- FAT3 | c.10296C>T p.V3432= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV53119177; called by muse, mutect2, varscan2
- FOXN1 | c.207C>T p.R69= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as COSV56880610, COSV56882121; called by muse, mutect2, varscan2
- FSTL5 | c.774T>C p.T258= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV60198796; called by muse, mutect2, varscan2
- KCNK15 | c.177C>T p.Y59= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100865783; called by muse, mutect2, varscan2
- KRTAP5-10 | c.375T>G p.G125= | Silent (SNP) | VAF 98/304 reads (32%) | catalogued as COSV64794517, COSV64794881; called by muse, varscan2
- LRP1B | c.8706G>A p.R2902= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as rs748118667, COSV101253992; called by muse, varscan2
- MUC16 | c.15855C>A p.P5285= | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as COSV67470382; called by muse, mutect2, varscan2
- PCNX1 | c.4200G>A p.L1400= | Silent (SNP) | VAF 50/314 reads (16%) | catalogued as COSV53095543; called by muse, mutect2, varscan2
- PKDREJ | c.1005C>A p.S335= | Silent (SNP) | VAF 60/310 reads (19%) | catalogued as COSV53549780; called by muse, mutect2, varscan2
- RBM10 | c.1146C>G p.A382= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV61309462; called by muse, mutect2, varscan2
- RBP3 | c.81G>T p.L27= | Silent (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- SCN5A | c.3438C>T p.N1146= (on ENST00000333535 / NM_198056.3; = p.N1145= on NM_000335.5) | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV61126433; called by muse, mutect2
- SERPINE1 | c.520T>C p.L174= | Silent (SNP) | VAF 24/408 reads (6%) | catalogued as COSV56169841; called by muse, mutect2
- SERPINE1 | c.522G>A p.L174= | Silent (SNP) | VAF 22/401 reads (5%) | catalogued as COSV56169851; called by muse, mutect2
- SNTB1 | c.1479A>T p.G493= | Silent (SNP) | VAF 13/260 reads (5%) | catalogued as COSV67326722; called by muse, mutect2
- SPEG | c.6618C>T p.P2206= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV56670408; called by muse, mutect2, varscan2
- STAC | c.459C>T p.G153= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs145962483, COSV56211730; called by muse, mutect2, varscan2
- TBC1D10C | c.453G>A p.S151= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs773786261, COSV56702478; called by muse, mutect2, varscan2
- TDRD5 | c.2502T>C p.N834= | Silent (SNP) | VAF 78/246 reads (32%) | catalogued as COSV54243932; called by muse, mutect2, varscan2
- TGFBR3 | c.96T>A p.P32= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV53026101; called by muse, varscan2
- TMEM255B | c.850C>T p.L284= | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as rs1451549626, COSV64712942; called by muse, mutect2, varscan2
- ZBTB43 | c.1185C>T p.L395= | Silent (SNP) | VAF 78/217 reads (36%) | catalogued as rs779351116, COSV65094829; called by muse, mutect2, varscan2
- ZNF536 | c.858C>T p.R286= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as rs770180821, COSV62821537; called by muse, mutect2, varscan2
- PRMT5 | c.110+69A>T | Intron (SNP) | VAF 45/148 reads (30%) | catalogued as COSV53546631; called by muse, mutect2, varscan2
